Somatic mutation profile of tumor specimen TARGET-10-PATEFF-09A (aliquot TARGET-10-PATEFF-09A-01D) from TARGET case TARGET-10-PATEFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,366 days).
Specimen TARGET-10-PATEFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2284db97-cd6b-4cad-92f4-c195834b2587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATEFF-14A (Bone Marrow Normal), aliquot TARGET-10-PATEFF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f3a4108-aa91-4adb-9505-76670a186b31

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Ins 2, 3'UTR 1, Intron 1, RNA 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.1348_1349insTGT p.T450delinsMS (on ENST00000357195 / NM_001282237.2; = p.T379delinsMS on NM_022898.3 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 18/42 reads (43%) | catalogued as COSV61738228, COSV61740901; called by mutect2, pindel, varscan2
- CDH11 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs769244467, COSV51756574; called by muse, mutect2, varscan2
- CNOT3 | c.2088G>A p.W696* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV55366928; called by muse, mutect2, varscan2
- CSMD2 | c.3527C>G p.T1176S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV53947546; called by muse, mutect2, varscan2
- HSD17B11 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866918643, COSV64154759, COSV64155064; called by muse, mutect2, varscan2
- JRKL | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53594998, COSV99567444; called by muse, mutect2
- PTEN | c.697delinsGG p.R233Gfs*10 | Frame Shift Ins (INS) | VAF 26/125 reads (21%) | catalogued as CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; called by pindel, varscan2*
- PTEN | c.737_738insAGGCC p.L247Gfs*11 | Frame Shift Ins (INS) | VAF 20/104 reads (19%) | catalogued as COSV64288404, COSV64297646, COSV64308731; called by pindel, varscan2
- SLC7A10 | c.1111T>A p.C371S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.542); called by muse, mutect2
- CATSPERG | c.1815C>T p.L605= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as rs570773350; called by muse, mutect2, varscan2
- HOXA3 | c.543C>T p.G181= | Silent (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- MAGEA11 | c.375C>T p.G125= | Silent (SNP) | VAF 28/33 reads (85%) | called by muse, mutect2, varscan2
- TAS1R2 | c.924G>A p.P308= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as rs1399645112, COSV64746444; called by muse, mutect2
- AC021218.1 | n.341G>A | RNA (SNP) | VAF 36/91 reads (40%) | catalogued as rs372254270; called by muse, mutect2, varscan2
- CTDSPL | c.*3305T>C | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- IRF1 | c.667+158_667+159insCGGAAAACCGGGG | Intron (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
